Somatic mutation profile of tumor specimen C3N-04279-01 (aliquot CPT0245500006) from CPTAC case C3N-04279, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.8 years (24,049 days).
Specimen C3N-04279-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c61185c0-5d30-4968-8904-8c2438351139.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04279-31 (Blood Derived Normal), aliquot CPT0245540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32718a60-4537-43dd-bd45-0ec0556767a7

The open-access MAF lists 216 somatic variants for this specimen: 158 protein-altering or splice-affecting, 34 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 34, Nonsense Mutation 17, Intron 12, Frame Shift Ins 7, RNA 7, 5'UTR 3, Splice Site 3, Splice Region 2, Frame Shift Del 2, 3'UTR 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 96/140 reads (69%) | catalogued as rs587784096, CM032971, COSV61771074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-2A>T p.X332_splice | Splice Site (SNP) | VAF 84/281 reads (30%) | hotspot (GDC flag); catalogued as CS159286, COSV52692098, COSV52692518, COSV53122371; called by muse, mutect2, varscan2
- TP53 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 123/389 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs967461896, CM165714, COSV52681947, COSV52682539, COSV52736779, COSV52752470; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AMZ2 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs782083530; called by muse, mutect2, varscan2
- ANAPC1 | c.1283C>G p.S428* | Nonsense Mutation (SNP) | VAF 13/145 reads (9%) | catalogued as rs896239864; called by muse, mutect2
- ARNT2 | c.1732C>G p.R578G | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100308811; called by muse, mutect2, varscan2
- ATP2B4 | c.3545A>G p.N1182S | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.031); catalogued as rs137927637; called by muse, mutect2, varscan2
- BMP7 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 155/553 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1292292967, COSV67782581; called by muse, mutect2, varscan2
- CASP8AP2 | c.1577A>G p.D526G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1458253389; called by muse, mutect2, varscan2
- CENPU | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.396); catalogued as COSV99859925; called by muse, mutect2, varscan2
- CORO6 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 117/318 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs774422358, COSV52181067; called by muse, mutect2, varscan2
- CWC22 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV55431952; called by muse, varscan2
- ENO4 | c.1663G>A p.G555S (on ENST00000622726; = p.G552S on NM_001242699.2) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1187882467; called by muse, mutect2, varscan2
- EPHB6 | c.2347G>T p.A783S | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1265014690; called by muse, mutect2, varscan2
- ETFA | c.882+6T>G | Splice Region (SNP) | VAF 31/104 reads (30%) | catalogued as rs746311782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXK1 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs763284610; called by muse, mutect2, varscan2
- FPR3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs779342164, COSV59328172; called by muse, mutect2, varscan2
- GON4L | c.5376G>T p.W1792C | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55185321; called by muse, mutect2, varscan2
- HS1BP3 | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1203858857; called by muse, mutect2, varscan2
- IFT88 | c.1735C>T p.Q579* (on ENST00000319980 / NM_001318493.2; = p.Q570* on NM_006531.5 and 9 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as rs776162848; called by muse, mutect2, varscan2
- IRF7 | c.416G>A p.R139Q (on ENST00000397566; = p.R126Q on NM_001572.5) | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV52761053; called by muse, mutect2, varscan2
- JMJD7 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs1255545079, COSV59828350; called by muse, mutect2, varscan2
- KLHL35 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 216/393 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs944197782, COSV61128555; called by muse, mutect2, varscan2
- LARGE1 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443560894, COSV61660696; called by muse, mutect2, varscan2
- MEX3B | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs978594058, COSV100314163; called by muse, mutect2, varscan2
- MUC3A | c.8810G>T p.R2937M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as rs1196082421; called by muse, varscan2
- MUC4 | c.7367C>T p.S2456L | Missense Mutation (SNP) | VAF 140/1274 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as rs1322099096; called by muse, varscan2
- MXRA5 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs144916947; called by muse, mutect2, varscan2
- NOD2 | c.2467C>A p.R823S | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.997); catalogued as rs575509512; called by muse, mutect2, varscan2
- OR2T6 | c.567T>A p.C189* | Nonsense Mutation (SNP) | VAF 63/154 reads (41%) | catalogued as rs756572193; called by muse, mutect2, varscan2
- OR4D6 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs775003268; called by muse, mutect2, varscan2
- OR8B3 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV63542316; called by muse, mutect2, varscan2
- OSBPL11 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as COSV56173499; called by muse, mutect2, varscan2
- OVCH2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs773982264, COSV71952995; called by muse, mutect2, varscan2
- P2RY1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV59310476; called by muse, mutect2, varscan2
- PARD3 | c.1400-2A>C p.X467_splice | Splice Site (SNP) | VAF 36/116 reads (31%) | catalogued as COSV60749955; called by muse, mutect2, varscan2
- PCDHA10 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 68/97 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV100249729; called by muse, mutect2, varscan2
- PFAS | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs752235279, COSV58979865; called by muse, mutect2, varscan2
- PKD1 | c.4946C>T p.T1649M | Missense Mutation (SNP) | VAF 146/556 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761106434; called by muse, mutect2, varscan2
- PPFIA2 | c.2201G>A p.R734K | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1244129849; called by muse, mutect2, varscan2
- PPP4R3A | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs746372581; called by muse, mutect2, varscan2
- PRR12 | c.110G>T p.G37V (on ENST00000615927; = p.G858V on NM_020719.3) | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as rs769901225; called by muse, mutect2, varscan2
- PTK2 | c.2759C>G p.S920W | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs760973444; called by muse, mutect2, varscan2
- PXDN | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 163/540 reads (30%) | catalogued as rs1316655042, COSV99413112; called by muse, mutect2, varscan2
- RYR1 | c.7231C>T p.P2411S | Missense Mutation (SNP) | VAF 137/454 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.127); catalogued as rs1333942098; called by muse, mutect2, varscan2
- SLC25A12 | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs927266622; called by muse, mutect2, varscan2
- SNX12 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 69/87 reads (79%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as COSV52145271; called by muse, mutect2, varscan2
- SPATC1 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 197/521 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV66298403; called by muse, mutect2, varscan2
- SYF2 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs376593141; called by muse, mutect2
- TECTA | c.2835G>C p.Q945H | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.947); catalogued as COSV50732287, COSV99878324; called by muse, mutect2, varscan2
- TESPA1 | c.1405G>C p.D469H (on ENST00000316577 / NM_001098815.3; = p.D331H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1340535794; called by muse, mutect2
- TMEM132D | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV70602594; called by muse, mutect2, varscan2
- TSC1 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 146/216 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99036859; called by muse, mutect2, varscan2
- TTN | c.85240G>A p.D28414N (on ENST00000591111; = p.D20990N on NM_003319.4) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | PolyPhen possibly damaging (0.856); catalogued as rs878879065; called by muse, mutect2, varscan2
- TTN | c.51911G>T p.G17304V (on ENST00000591111; = p.G9880V on NM_003319.4) | Missense Mutation (SNP) | VAF 54/159 reads (34%) | PolyPhen probably damaging (1); catalogued as CD1514723; called by muse, mutect2, varscan2
- WDTC1 | c.868dup p.E290Gfs*7 | Frame Shift Ins (INS) | VAF 36/126 reads (29%) | catalogued as rs747972901; called by mutect2, varscan2
- ABCA6 | c.3521dup p.L1174Ffs*18 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- ACACB | c.5701G>C p.D1901H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADPGK | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 47/141 reads (33%) | called by muse, mutect2, varscan2
- AJUBA | c.1108+1_1108+3del p.X370_splice | Splice Site (DEL) | VAF 36/53 reads (68%) | called by pindel, varscan2
- ANK1 | c.3523A>C p.S1175R | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ARMC5 | c.344C>A p.S115* | Nonsense Mutation (SNP) | VAF 146/424 reads (34%) | called by muse, mutect2, varscan2
- ART1 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP8A1 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- ATR | c.4131A>T p.Q1377H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AVP | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 136/397 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AVPR1A | c.1095C>A p.C365* | Nonsense Mutation (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- B4GAT1 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BLMH | c.1083G>C p.E361D | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CATSPER3 | c.224T>A p.I75K | Missense Mutation (SNP) | VAF 122/173 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CCAR1 | c.3001G>A p.G1001R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC93 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.156); called by muse, varscan2
- CCNT2 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CELSR1 | c.6607T>A p.W2203R | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPV | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP57L1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CERK | c.776_780del p.L259Hfs*41 | Frame Shift Del (DEL) | VAF 51/217 reads (24%) | called by mutect2, pindel, varscan2
- CLASRP | c.1581C>A p.S527R | Missense Mutation (SNP) | VAF 121/428 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CLCN5 | c.2053C>A p.L685I | Missense Mutation (SNP) | VAF 82/121 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CLIC5 | c.914A>T p.K305M (on ENST00000185206 / NM_001370649.1; = p.K146M on NM_016929.5) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CNTRL | c.2280C>A p.F760L | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CPSF1 | c.237G>C p.M79I | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CRYBG3 | c.3931G>C p.E1311Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CTNNA3 | c.1973A>G p.D658G | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DCHS1 | c.7622G>A p.G2541E | Missense Mutation (SNP) | VAF 128/365 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DDX42 | c.2430T>A p.Y810* | Nonsense Mutation (SNP) | VAF 65/206 reads (32%) | called by muse, mutect2, varscan2
- DDX54 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 143/430 reads (33%) | called by muse, mutect2, varscan2
- DENND2C | c.2509A>C p.M837L (on ENST00000393274 / NM_001256404.2; = p.M780L on NM_198459.4) | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DISP1 | c.4198G>A p.G1400R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYNC2H1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ESCO1 | c.1649C>A p.S550* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- FAM114A1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- FANCL | c.610A>T p.M204L | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FBXO41 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- HK3 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS1BP3 | c.362A>T p.K121M | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- IGHG4 | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 324/896 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH1 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 107/210 reads (51%) | called by muse, mutect2, varscan2
- JUNB | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 152/446 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KDM2B | c.1218_1219insAG p.W407Sfs*76 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- KRT15 | c.253_276del p.V85_G92del | In Frame Del (DEL) | VAF 55/237 reads (23%) | called by mutect2, pindel, varscan2
- LGALSL | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LRRC37A2 | c.3776C>G p.S1259C | Missense Mutation (SNP) | VAF 195/862 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- LY75 | c.1945A>T p.S649C | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- MAP2 | c.2307A>G p.I769M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MAP7D2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST2 | c.4082G>T p.R1361L | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- MDGA2 | c.1172dup p.S392Vfs*25 (on ENST00000399232 / NM_001113498.2; = p.S94Vfs*25 on NM_182830.4) | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- MYO1F | c.2544G>T p.K848N | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NECTIN3 | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- NOS2 | c.3413A>C p.K1138T | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP35 | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- OCSTAMP | c.1619T>C p.I540T | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR5V1 | c.558C>G p.I186M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- OSBPL10 | c.506G>C p.C169S | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE5A | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PHACTR3 | c.719A>T p.K240M | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PIANP | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by mutect2, varscan2
- PLEKHG3 | c.3169G>C p.A1057P (on ENST00000394691; = p.A1113P on NM_001308147.2) | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PPEF2 | c.747-6A>G | Splice Region (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- PSG6 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RALGAPA2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- REV3L | c.1907dup p.H636Qfs*7 | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- RGPD8 | c.4471A>G p.I1491V | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RSPH9 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 115/378 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SCLT1 | c.575T>A p.L192Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SEMA6D | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SH3GL1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 106/307 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIX6 | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SLC27A2 | c.1417A>C p.N473H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SMCHD1 | c.2528dup p.L845Sfs*6 | Frame Shift Ins (INS) | VAF 13/105 reads (12%) | called by mutect2, pindel, varscan2
- SNED1 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRNP48 | c.669_682del p.S224Efs*11 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel
- SPATA31D1 | c.1096T>C p.S366P | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SPTA1 | c.4699G>C p.E1567Q | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ST6GALNAC2 | c.902A>T p.Y301F | Missense Mutation (SNP) | VAF 42/146 reads (29%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STYXL2 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNM | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 149/491 reads (30%) | called by muse, mutect2, varscan2
- TFPT | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 115/329 reads (35%) | called by muse, mutect2, varscan2
- TMEM265 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- TNFSF13B | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNRC18 | c.5996G>C p.S1999T | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TOMM20L | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- TRAF3IP2 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC25 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TTC7B | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 87/129 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTLL12 | c.266A>G p.Q89R | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBXN2A | c.527dup p.Q177Tfs*15 | Frame Shift Ins (INS) | VAF 19/75 reads (25%) | called by pindel, varscan2
- UHRF1BP1L | c.4249T>C p.F1417L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- VAV2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WDR61 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- XPO6 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- YTHDF1 | c.419A>T p.Q140L | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZNF160 | c.1471A>T p.T491S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ZNF205 | c.1054A>T p.I352F | Missense Mutation (SNP) | VAF 125/413 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF350 | c.1096A>G p.R366G | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF527 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ZNF639 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ACY3 | c.618C>T p.I206= | Silent (SNP) | VAF 311/444 reads (70%) | catalogued as rs774215138; called by muse, mutect2, varscan2
- ATP1B1 | c.150C>T p.F50= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as COSV63179373; called by muse, varscan2
- C16orf54 | c.9G>A p.L3= | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CCDC87 | c.1986G>A p.R662= | Silent (SNP) | VAF 89/727 reads (12%) | called by muse, mutect2, varscan2
- CDH6 | c.936G>A p.G312= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- CDH9 | c.366T>C p.S122= | Silent (SNP) | VAF 58/163 reads (36%) | called by muse, mutect2, varscan2
- CPSF1 | c.345G>A p.L115= | Silent (SNP) | VAF 87/287 reads (30%) | called by muse, mutect2, varscan2
- DMXL2 | c.2493C>T p.G831= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- DVL3 | c.1845G>A p.G615= | Silent (SNP) | VAF 176/587 reads (30%) | catalogued as COSV53049474; called by muse, mutect2, varscan2
- FCGBP | c.5940G>A p.E1980= | Silent (SNP) | VAF 162/1235 reads (13%) | called by muse, mutect2, varscan2
- GCKR | c.1740C>T p.F580= | Silent (SNP) | VAF 142/444 reads (32%) | catalogued as COSV99269049; called by muse, mutect2, varscan2
- IRX4 | c.633G>A p.R211= | Silent (SNP) | VAF 98/272 reads (36%) | called by muse, varscan2
- LOXHD1 | c.4239C>T p.C1413= | Silent (SNP) | VAF 49/79 reads (62%) | catalogued as rs886053827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MME | c.207G>A p.L69= | Silent (SNP) | VAF 48/249 reads (19%) | called by muse, mutect2, varscan2
- MUC4 | c.4839C>T p.H1613= | Silent (SNP) | VAF 134/930 reads (14%) | called by muse, varscan2
- NPHP3 | c.3072A>G p.P1024= | Silent (SNP) | VAF 57/224 reads (25%) | called by muse, mutect2, varscan2
- NRXN1 | c.1704G>A p.K568= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV58444076; called by muse, mutect2, varscan2
- NXPH1 | c.174C>T p.L58= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV101339739; called by muse, mutect2, varscan2
- PCDHA2 | c.573T>A p.S191= | Silent (SNP) | VAF 70/99 reads (71%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1989C>T p.A663= | Silent (SNP) | VAF 282/436 reads (65%) | called by muse, mutect2, varscan2
- PDCD11 | c.1158G>C p.L386= | Silent (SNP) | VAF 75/239 reads (31%) | called by muse, mutect2, varscan2
- PLA2G4A | c.541T>C p.L181= | Silent (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- PLPPR3 | c.1428G>C p.P476= (on ENST00000520876 / NM_001270366.2; = p.P504= on NM_024888.2) | Silent (SNP) | VAF 137/251 reads (55%) | catalogued as rs546087828; called by muse, varscan2
- PPP2R5E | c.531T>C p.D177= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs776446375; called by muse, mutect2, varscan2
- PRAMEF27 | c.942G>A p.K314= | Silent (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- PRB1 | c.183C>A p.P61= | Silent (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- PRKDC | c.1533A>T p.S511= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- PSG6 | c.486G>A p.E162= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs778366621; called by muse, mutect2, varscan2
- RSPH6A | c.81G>A p.R27= | Silent (SNP) | VAF 124/375 reads (33%) | catalogued as rs780438780; called by muse, mutect2, varscan2
- TACC3 | c.21C>T p.N7= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs760825890; called by muse, mutect2, varscan2
- UGGT1 | c.1437G>A p.E479= | Silent (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- UMPS | c.1056A>G p.K352= | Silent (SNP) | VAF 54/252 reads (21%) | called by muse, mutect2, varscan2
- ZNHIT2 | c.486G>T p.P162= | Silent (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- ZNHIT6 | c.24A>G p.E8= | Silent (SNP) | VAF 9/32 reads (28%) | called by mutect2, varscan2
- AC105942.1 | n.1178C>T | RNA (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- ANG | c.*29C>G | 3'UTR (SNP) | VAF 91/386 reads (24%) | catalogued as rs746829799; called by muse, mutect2, varscan2
- ARMC8 | c.1822-1375G>C | Intron (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- CTSLP8 | n.917A>T | RNA (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- DHRSX | c.286+16308C>T | Intron (SNP) | VAF 49/95 reads (52%) | catalogued as rs780544080; called by muse, mutect2, varscan2
- DUSP15 | c.426+1120G>A | Intron (SNP) | VAF 98/319 reads (31%) | catalogued as rs1230034187; called by muse, mutect2, varscan2
- DYNC1H1 | c.12400-31C>T | Intron (SNP) | VAF 176/457 reads (39%) | catalogued as rs185533516; called by muse, mutect2, varscan2
- FAM193B | c.1275+974G>A | Intron (SNP) | VAF 117/179 reads (65%) | catalogued as rs970691851; called by muse, mutect2, varscan2
- GGA3 | c.1193-10C>A | Intron (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- HMBOX1 | c.-38C>A | 5'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99816568; called by muse, mutect2, varscan2
- KLF6 | c.*2767C>G | 3'UTR (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- MICAL1 | c.2305-35C>G | Intron (SNP) | VAF 111/350 reads (32%) | catalogued as rs750899673, COSV57804652; called by muse, mutect2, varscan2
- OR10V2P | n.410G>A | RNA (SNP) | VAF 101/198 reads (51%) | called by muse, mutect2, varscan2
- PPFIA4 | c.1697+10G>T | Intron (SNP) | VAF 142/468 reads (30%) | called by muse, mutect2, varscan2
- PREP | c.-134A>G | 5'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- RAP1GAP | c.-121G>A | 5'UTR (SNP) | VAF 62/198 reads (31%) | called by muse, mutect2, varscan2
- RPGR | c.2520+1405C>A | Intron (SNP) | VAF 80/130 reads (62%) | catalogued as COSV100139784, COSV58833511; called by muse, mutect2, varscan2
- SNORD115-35 | n.64T>A | RNA (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2375A>T | RNA (SNP) | VAF 298/445 reads (67%) | called by muse, mutect2, varscan2
- SPCS2P4 | n.398C>T | RNA (SNP) | VAF 44/160 reads (28%) | called by muse, varscan2
- SPCS2P4 | n.250C>T | RNA (SNP) | VAF 90/252 reads (36%) | called by muse, varscan2
- TCN2 | c.65-578C>A | Intron (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- TGFBR3 | c.738-19C>A | Intron (SNP) | VAF 28/92 reads (30%) | called by muse, varscan2
- TM4SF1 | c.594+23C>G | Intron (SNP) | VAF 33/134 reads (25%) | catalogued as COSV59524729; called by muse, mutect2
